Somatic mutation profile of tumor specimen MP2PRT-PAVUFJ-TMP1-A (aliquot MP2PRT-PAVUFJ-TMP1-A-1-0-D-A83Q-36) from MP2PRT case MP2PRT-PAVUFJ, project MP2PRT-ALL (Molecular Profiling to Predict Response to Treatment for Acute Lymphoblastic Leukemia). Sex at birth: male; Vital status: Alive; Primary diagnosis: Common precursor B ALL; Tissue or organ of origin: Bone marrow; Age at diagnosis: 2.5 years (931 days).
Specimen MP2PRT-PAVUFJ-TMP1-A: Sample type: Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Whole Bone Marrow; Biospecimen anatomic site: Bone Marrow; Preservation method: Cryopreserved.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) e149a5b3-2cf6-4aba-95e0-6ba83b312ec0.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MP2PRT-PAVUFJ-NB1-A (Blood Derived Cancer - Peripheral Blood, Post-treatment; tissue type Normal — post-treatment blood used as the germline comparator), aliquot MP2PRT-PAVUFJ-NB1-A-1-0-D-A83Q-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/eeaf185f-d883-47d0-a541-6aab42793964

The open-access MAF lists 30 somatic variants for this specimen: 16 protein-altering or splice-affecting, 14 silent.
By variant classification: Silent 14, Missense Mutation 12, Nonsense Mutation 3, In Frame Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- TTN | c.52408C>T p.R17470* (on ENST00000591111; = p.R10046* on NM_003319.4) | Nonsense Mutation (SNP) | VAF 106/318 reads (33%) | catalogued as rs72646831, CM121821; ClinVar: likely pathogenic / pathogenic / uncertain significance; called by muse, mutect2, varscan2
- FLT1 | c.2311C>G p.L771V | Missense Mutation (SNP) | VAF 36/426 reads (8%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.916); catalogued as rs1279149819, COSV56718598; called by muse, mutect2
- GPR151 | c.348G>A p.W116* | Nonsense Mutation (SNP) | VAF 14/288 reads (5%) | catalogued as rs1191453849; called by muse, mutect2
- IGSF9B | c.3544C>T p.R1182W | Missense Mutation (SNP) | VAF 101/713 reads (14%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.985); catalogued as rs765118637, COSV58063635; called by muse, mutect2, varscan2
- RRBP1 | c.3962C>T p.S1321L (on ENST00000377813 / NM_001365613.2; = p.S888L on NM_004587.3) | Missense Mutation (SNP) | VAF 37/288 reads (13%) | SIFT tolerated (0.07); PolyPhen benign (0.005); catalogued as rs146214602; called by muse, mutect2, varscan2
- SPTBN5 | c.9119G>A p.R3040Q | Missense Mutation (SNP) | VAF 28/648 reads (4%) | SIFT tolerated (0.54); PolyPhen benign (0.007); catalogued as rs370002662; called by muse, mutect2
- ZNF257 | c.436C>G p.Q146E | Missense Mutation (SNP) | VAF 33/288 reads (11%) | SIFT deleterious (0.02); PolyPhen benign (0.012); catalogued as COSV71312573; called by muse, mutect2, varscan2
- ADAMTS20 | c.5294C>T p.S1765F | Missense Mutation (SNP) | VAF 31/215 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- ATP9B | c.12G>C p.Q4H | Missense Mutation (SNP) | VAF 53/544 reads (10%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0); called by muse, mutect2
- IGLV4-69 | c.358dup p.*120P | In Frame Ins (INS) | VAF 56/140 reads (40%) | called by mutect2, varscan2
- KRAS | c.355G>C p.D119H | Missense Mutation (SNP) | VAF 30/372 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2
- OTOP1 | c.898C>G p.Q300E | Missense Mutation (SNP) | VAF 18/423 reads (4%) | SIFT tolerated (0.17); PolyPhen benign (0.179); called by muse, mutect2
- PTPRF | c.1303G>C p.E435Q | Missense Mutation (SNP) | VAF 36/660 reads (5%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.952); called by muse, mutect2
- SKOR2 | c.2926C>T p.Q976* | Nonsense Mutation (SNP) | VAF 24/235 reads (10%) | called by muse, mutect2, varscan2
- TOP2B | c.1667A>G p.K556R (on ENST00000264331 / NM_001330700.2; = p.K551R on NM_001068.3) | Missense Mutation (SNP) | VAF 57/174 reads (33%) | SIFT tolerated (0.19); PolyPhen benign (0.044); called by muse, mutect2, varscan2
- ZNF419 | c.131T>A p.L44H | Missense Mutation (SNP) | VAF 26/502 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2
- ACSBG1 | c.207G>A p.V69= | Silent (SNP) | VAF 24/384 reads (6%) | catalogued as rs1405879268; called by muse, mutect2
- AGXT | c.120C>T p.A40= | Silent (SNP) | VAF 26/501 reads (5%) | catalogued as rs1333685290, COSV56755129; called by muse, mutect2
- AQP1 | c.174G>A p.L58= | Silent (SNP) | VAF 87/557 reads (16%) | catalogued as rs1258289620; called by muse, mutect2, varscan2
- CHRM3 | c.178C>T p.L60= | Silent (SNP) | VAF 45/370 reads (12%) | called by muse, mutect2, varscan2
- DNAH5 | c.10404C>T p.A3468= | Silent (SNP) | VAF 34/235 reads (14%) | catalogued as COSV99454062; called by muse, varscan2
- DOK2 | c.318G>A p.V106= | Silent (SNP) | VAF 42/384 reads (11%) | catalogued as rs1470129487; called by mutect2, varscan2
- IGLV4-69 | c.359delinsCC p.*120P | Silent (INS) | VAF 51/200 reads (26%) | called by mutect2*, pindel, varscan2*
- KLLN | c.504C>T p.L168= | Silent (SNP) | VAF 44/387 reads (11%) | called by muse, mutect2, varscan2
- MTIF2 | c.858C>T p.A286= | Silent (SNP) | VAF 52/293 reads (18%) | catalogued as rs373839804; called by muse, mutect2
- MYO5B | c.2133C>G p.V711= | Silent (SNP) | VAF 14/358 reads (4%) | called by muse, mutect2
- PCDH19 | c.663C>T p.T221= | Silent (SNP) | VAF 18/382 reads (5%) | catalogued as COSV55258376; called by muse, mutect2
- POU2F2 | c.1050G>A p.Q350= (on ENST00000526816 / NM_001207025.3; = p.Q334= on NM_002698.5) | Silent (SNP) | VAF 67/475 reads (14%) | catalogued as COSV100657430; called by muse, mutect2, varscan2
- SPTBN5 | c.60G>A p.R20= | Silent (SNP) | VAF 22/678 reads (3%) | called by muse, mutect2
- ZNF521 | c.3732G>C p.L1244= | Silent (SNP) | VAF 39/369 reads (11%) | catalogued as COSV64126980; called by muse, mutect2, varscan2
